Somatic mutation profile of tumor specimen TCGA-CV-6436-01A (aliquot TCGA-CV-6436-01A-11D-1683-08) from TCGA case TCGA-CV-6436, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 62.7 years (22,885 days).
Specimen TCGA-CV-6436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86f7477e-4ae1-4b1e-b6d4-68ac038fd3a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6436-11A (Solid Tissue Normal), aliquot TCGA-CV-6436-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea4c44af-cbe0-4f7d-adce-8fea9375da83

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 53, Silent 18, Nonsense Mutation 7, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- EPHA7 | c.1966G>T p.G656W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65180996, COSV65192193; called by muse, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53032869; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.2980C>T p.R994W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as rs757854282, COSV61870013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59608598; called by muse, mutect2, varscan2
- ACAD10 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV58160792; called by muse, mutect2, varscan2
- ADAM21 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1366338508, COSV50802675; called by muse, varscan2
- AGBL2 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs780832704, COSV54093037, COSV54093744; called by muse, mutect2, varscan2
- AP3B2 | c.2611C>T p.R871W (on ENST00000261722; = p.R865W on NM_004644.5) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772198872, COSV55612587; called by muse, mutect2, varscan2
- APPL2 | c.677T>C p.L226S | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV51589666; called by muse, mutect2, varscan2
- CASP8 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV51856363; called by muse, mutect2, varscan2
- CATSPERD | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV58466597; called by muse, mutect2, varscan2
- CBX4 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53967072; called by muse, mutect2, varscan2
- CCDC14 | c.1111A>G p.T371A (on ENST00000488653; = p.T323A on NM_022757.5) | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746087919, COSV59946877; called by muse, mutect2, varscan2
- CCDC8 | c.1149C>G p.H383Q | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1259007630, COSV56774321; called by muse, mutect2, varscan2
- CFAP69 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV60187353; called by muse, mutect2, varscan2
- CLVS2 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs1267203230, COSV51560839; called by muse, mutect2, varscan2
- DDX54 | c.2352A>C p.E784D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV58375274; called by muse, mutect2, varscan2
- DENND2B | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 130/353 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs369103162; called by muse, mutect2, varscan2
- DENND5B | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs576115388, COSV60900297; called by muse, mutect2, varscan2
- DYRK1B | c.250_252del p.E84del | In Frame Del (DEL) | VAF 20/89 reads (22%) | catalogued as rs1431027379; called by mutect2, pindel, varscan2
- EIF4G1 | c.1240G>A p.D414N (on ENST00000346169 / NM_198241.3; = p.D218N on NM_004953.5) | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV59990307; called by muse, mutect2, varscan2
- ETV6 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV67149244; called by muse, mutect2, varscan2
- FAM43A | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61673391; called by muse, mutect2, varscan2
- FLG | c.5677G>A p.D1893N | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); catalogued as rs780992659, COSV64245753; called by muse, mutect2, varscan2
- GCM2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780594439, CM099924, COSV65276268, COSV65276393; called by muse, mutect2, varscan2
- GPR20 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66683995; called by muse, mutect2, varscan2
- H2BC5 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV56802117, COSV56802899; called by muse, mutect2, varscan2
- HSD17B11 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV64154392, COSV64155014; called by muse, mutect2
- ISLR2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as COSV62301828; called by muse, mutect2, varscan2
- JAKMIP1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1177961270, COSV51522392; called by muse, mutect2
- KCNQ2 | c.1366G>A p.G456R (on ENST00000359125 / NM_172107.4; = p.G428R on NM_004518.6) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.404); catalogued as COSV100609954; called by mutect2, varscan2
- KDM3B | c.4414C>T p.R1472* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs1561796122, COSV100069409, COSV58693606; called by muse, mutect2, varscan2
- KSR2 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs772671793, COSV56677726; called by muse, mutect2, varscan2
- LGMN | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs746438674, COSV58404622; called by muse, mutect2, varscan2
- LMCD1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.506); catalogued as COSV50090361; called by muse, varscan2
- MAGT1 | c.336C>G p.N112K (on ENST00000618282 / NM_001367916.1; = p.N144K on NM_032121.5) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV63781323; called by muse, mutect2, varscan2
- MEGF6 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755636118, COSV53888581; called by muse, mutect2, varscan2
- NTSR2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145680805; called by muse, mutect2, varscan2
- OAZ3 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs757467800, COSV58618136; called by muse, mutect2
- OR4C15 | c.685C>A p.H229N (on ENST00000314644; = p.H175N on NM_001001920.2) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV58952556, COSV58956358; called by muse, mutect2, varscan2
- PCDHA8 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); catalogued as COSV65334911, COSV65336054; called by muse, mutect2, varscan2
- PDILT | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56703882; called by muse, mutect2, varscan2
- PLEKHA6 | c.2318C>G p.P773R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1465261841, COSV55338245; called by muse, mutect2
- PPP4R4 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs745732168, COSV58553728; called by muse, mutect2
- PTPRA | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as COSV53780465; called by muse, mutect2, varscan2
- RETREG3 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1190178899, COSV100515110, COSV58703734; called by muse, mutect2, varscan2
- RXRA | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62684055; called by muse, mutect2, varscan2
- SF1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV99918072; called by muse, mutect2, varscan2
- SLC5A4 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150790454; called by muse, mutect2, varscan2
- SRPK2 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61960442; called by muse, mutect2, varscan2
- ST8SIA5 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | PolyPhen possibly damaging (0.568); catalogued as rs373700133; called by muse, mutect2, varscan2
- TDRD3 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52155540; called by muse, mutect2, varscan2
- TGFBR3 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV53029351; called by muse, mutect2, varscan2
- TRIM48 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV101338231; called by muse, mutect2, varscan2
- TTF1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57502195; called by muse, mutect2, varscan2
- VPS13A | c.4489delinsTT p.V1497Ffs*3 | Frame Shift Ins (INS) | VAF 37/129 reads (29%) | catalogued as COSV62435310; called by mutect2*, pindel, varscan2*
- WDR44 | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54162423; called by muse, mutect2, varscan2
- ZNF614 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 42/199 reads (21%) | catalogued as COSV54545807; called by muse, mutect2, varscan2
- HS3ST6 | c.883_897del p.G295_R299del | In Frame Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- RPSA | c.594_604del p.M198Ifs*7 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- VPS13A | c.4488dup p.V1497Cfs*3 | Frame Shift Ins (INS) | VAF 38/101 reads (38%) | called by mutect2, varscan2
- AFF1 | c.1989G>A p.V663= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV57122595; called by muse, mutect2, varscan2
- ARVCF | c.2472C>T p.H824= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV52889091; called by muse, mutect2, varscan2
- ATP10A | c.1752G>A p.T584= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs769840917, COSV63521275; called by muse, mutect2, varscan2
- C16orf78 | c.612C>T p.T204= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100147601; called by muse, mutect2, varscan2
- COX7A2 | c.183G>A p.P61= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as COSV57874149; called by muse, mutect2, varscan2
- DIDO1 | c.5574C>T p.A1858= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs760794417, COSV56630648; called by muse, mutect2, varscan2
- DKK3 | c.999G>A p.A333= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs746164903, COSV58869702; called by muse, mutect2, varscan2
- DNAH2 | c.4140C>T p.L1380= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs763629221, COSV66719880; called by muse, mutect2, varscan2
- GFRA3 | c.624C>T p.A208= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs754570944, COSV51229451; called by muse, mutect2, varscan2
- GRIN2A | c.657G>A p.L219= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV58049540; called by muse, mutect2, varscan2
- IGHG2 | c.147C>T p.G49= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs750603355; called by muse, mutect2, varscan2
- IKBIP | c.1005G>A p.E335= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs201283576, COSV61082344; called by muse, mutect2, varscan2
- MPP7 | c.567C>T p.N189= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs780437897, COSV61733050; called by muse, mutect2, varscan2
- NUP160 | c.2221T>C p.L741= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV65855369; called by muse, mutect2, varscan2
- SLC28A3 | c.1083C>T p.H361= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs777707463, COSV66154419; called by muse, mutect2, varscan2
- UTRN | c.7665G>A p.E2555= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV62311659; called by muse, mutect2, varscan2
- WDR11 | c.552C>T p.F184= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs761296035, COSV54791413; called by muse, mutect2, varscan2
- ZC3H7B | c.2778G>C p.L926= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV60963800; called by muse, varscan2
